Gene-level copy-number profile of tumor specimen TCGA-97-8179-01A from TCGA case TCGA-97-8179, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acinar cell carcinoma; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IA; Age at diagnosis: 72.0 years (26,305 days).
Specimen TCGA-97-8179-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LUAD.b94568e6-1760-496d-80c5-9ad6182283a4.gene_level_copy_number.v36.tsv, workflow ASCAT2 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-97-8179-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 364 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/0239e1f1-7c8c-4be8-8d3b-ccd1dba30edb

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 936; copy number 1: 2,523; copy number 2: 27,486; copy number 3: 12,074; copy number 4: 10,343; copy number 5: 3,603; copy number 6: 2,281; copy number 7: 1,013.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-97-8179-01A-11D-2283-01): tumor purity 0.48, ploidy 2.83, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 11 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr5:5,142,138–5,176,214, 1 gene (within-gene range 0–2): AC022424.1.
- chr17:18,450,244–18,551,705, 9 genes: KRT16P4, AL353997.1, AL353997.4, TNPO1P2, LGALS9C, NOS2P2, FAM106A, USP32P2, SRP68P2.
- chr20:1,591,392–1,591,848, 1 gene: AL049634.3.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 6,897 genes in 32 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:143,541,768–248,919,946, 2,595 genes, copy number 6–7 (broad region; genes not listed).
- chr4:28,225,969–31,558,831, 26 genes, copy number 5: AC093791.2, AC093791.1, AC097480.1, AC097480.2, RN7SL101P, MIR4275, MESTP3, LINC02364, AC068944.2, AC068944.1, AC109349.1, LINC02472, AC092593.2, AC092593.1, U6, EEF1A1P21, AC097510.1, RPS3AP17, AC106868.1, AC098595.1, PCDH7, AC097716.1, MTCYBP43, LINC02497, AC104071.1, LINC02501.
- chr4:32,005,076–32,022,483, 1 gene, copy number 5: AC097654.1.
- chr4:68,509,441–68,670,652, 6 genes, copy number 7: UGT2B29P, UGT2B17, AC147055.2, AC147055.4, AC147055.3, UGT2B15.
- chr5:5,420,664–9,903,852, 84 genes, copy number 5 (broad region; genes not listed).
- chr5:10,971,836–11,904,446, 1 gene, copy number 5 (within-gene range 4–5): CTNND2.
- chr5:12,297,399–28,809,291, 191 genes, copy number 5 (broad region; genes not listed).
- chr5:28,897,785–28,927,459, 4 genes, copy number 5: AC010385.2, LSP1P3, AC010385.1, AC010385.3.
- chr6:167,607–29,681,155, 670 genes, copy number 5–6 (broad region; genes not listed).
- chr6:30,839,526–65,707,226, 798 genes, copy number 5 (within-gene range 4–5) (broad region; genes not listed).
- chr6:71,028,582–71,652,611, 20 genes, copy number 6: AL096709.1, BECN1P2, U3, LYPLA1P3, RNU6-411P, AL589935.1, AL589935.3, AL589935.2, OGFRL1, AL136164.2, AL136164.1, LINC00472, MIR30C2, AL136164.3, MIR30A, LINC01626, AL035467.2, AL035467.1, KRT19P1, RNU4-66P.
- chr6:156,976,294–156,977,072, 1 gene, copy number 5: AL162578.1.
- chr6:159,725,585–161,274,061, 34 genes, copy number 5 (within-gene range 2–5): WTAP, SOD2-OT1, ACAT2, TCP1, SNORA20, SNORA29, MRPL18, PNLDC1, AL035691.1, MAS1, IGF2R, AIRN, CHP1P2, SLC22A1, AL645733.1, SLC22A2, AL162582.1, SLC22A3, AL591069.1, LPAL2, LPA, AL109933.2, AL109933.1, PLG, AL109933.5, AL109933.4, AL109933.3, AL391361.2, AL391361.1, AL139393.2, AL139393.1, MAP3K4-AS1, MAP3K4, AGPAT4.
- chr6:161,353,679–161,446,016, 2 genes, copy number 5: AL132982.1, AL138716.1.
- chr7:52,165,235–54,621,131, 26 genes, copy number 5: AC079763.1, AC006320.1, AC006459.1, SGO1P2, AC074397.1, POM121L12, HAUS6P1, RNF138P2, RNU1-14P, RN7SKP218, AC009468.2, AC009468.1, LINC01446, RNU2-29P, RAC1P9, AC074348.1, HAUS6P3, LINC02854, AC092848.2, AC092848.1, LINC01445, SLC25A5P3, VSTM2A, VSTM2A-OT1, AC011228.1, RNU6-1125P.
- chr7:151,556,124–159,233,377, 121 genes, copy number 5 (within-gene range 4–5) (broad region; genes not listed).
- chr8:46,028,804–46,028,892, 1 gene, copy number 7: AC118650.1.
- chr8:74,548,543–142,812,120, 951 genes, copy number 5–6 (within-gene range 2–6) (broad region; genes not listed).
- chr10:44,712–42,367,974, 681 genes, copy number 5–6 (broad region; genes not listed).
- chr13:102,263,046–103,066,417, 21 genes, copy number 6: RPL39P29, FGF14-IT1, AL356266.1, FGF14-AS1, FGF14-AS2, LINC00555, AL158063.1, TPP2, METTL21C, CCDC168, LINC00283, AL157769.1, TEX30, POGLUT2, BIVM-ERCC5, BIVM, ERCC5, METTL21EP, AL137246.1, AL137246.2, SLC10A2.
- chr13:104,814,327–104,815,069, 1 gene, copy number 6: RPL7P45.
- chr14:56,683,421–56,683,741, 1 gene, copy number 7: AL161757.1.
- chr15:87,576,929–87,579,866, 1 gene, copy number 6: LINC00052.
- chr16:5,239,802–7,713,340, 1 gene, copy number 5 (within-gene range 4–5): RBFOX1.
- chr16:5,838,131–8,112,756, 16 genes, copy number 5: AC012175.1, AC009135.2, AC009135.1, AC006112.1, AC007223.1, AC007012.2, AC007012.1, RNU7-99P, RNU6-457P, RNU6-328P, AC022206.1, AC007222.2, AC007222.1, AC005774.2, AC005774.1, AC093515.1.
- chr16:58,705,799–65,863,784, 58 genes, copy number 5: AC012183.1, GOT2, AC106793.1, RNU6-1155P, RN7SL143P, GEMIN8P2, RPL12P36, AC092378.1, Metazoa_SRP, RPS27P27, AC092121.1, RNU4-58P, DUXAP11, APOOP5, LINC02141, AC009094.1, AC009081.2, AC018554.1, NPAP1L, AC009081.1, GNPATP, AC009169.1, RPS27AP16, AC092125.2, CDH8, AC092125.1, RN7SKP76, AC012174.1, RNU6-21P, AC009161.2, AC009161.1, AC009110.1, AC010546.1, AC040174.1, AC040174.2, UBE2FP2, AC138305.1, RPS15AP34, AC138305.2, AC138305.3, AC018846.1, LINC02165, AC092337.1, AC093536.2, AC012322.1, AC093536.1, AC092131.1, PPIAP48, AC009101.1, CDH11, AC010533.1, LINC02126, AC009055.2, AC009055.1, LINC00922, AC092138.2, AC092138.1, AC022164.1.
- chr17:12,390,738–12,642,854, 3 genes, copy number 5 (within-gene range 3–5): AC084167.1, LINC00670, AC068442.1.
- chr17:70,053,429–70,241,761, 4 genes, copy number 5 (within-gene range 3–5): KCNJ16, KCNJ2-AS1, KCNJ2, CALM2P1.
- chr18:20,946,906–32,131,561, 188 genes, copy number 5 (broad region; genes not listed).
- chr18:32,176,050–32,220,404, 3 genes, copy number 5 (within-gene range 2–5): RNA5SP453, MEP1B, CLUHP6.
- chr20:1,629,152–16,053,197, 249 genes, copy number 5 (broad region; genes not listed).
- chr21:12,999,676–20,828,622, 138 genes, copy number 5–7 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 616. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
